Somatic mutation profile of tumor specimen TCGA-EB-A5UL-06A (aliquot TCGA-EB-A5UL-06A-11D-A30X-08) from TCGA case TCGA-EB-A5UL, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 71.7 years (26,178 days).
Specimen TCGA-EB-A5UL-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09292562-f6aa-440b-94f5-773e69e5ee3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A5UL-10A (Blood Derived Normal), aliquot TCGA-EB-A5UL-10A-01D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b33d1f5c-f6bd-48d5-9899-505f915f1874

The open-access MAF lists 530 somatic variants for this specimen: 352 protein-altering or splice-affecting, 167 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 312, Silent 167, Nonsense Mutation 29, Intron 6, Splice Site 5, Splice Region 5, 3'UTR 2, RNA 2, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCC | c.1789C>T p.R597* | Nonsense Mutation (SNP) | VAF 18/80 reads (23%) | catalogued as rs1085307773, COSV59101172; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 77/161 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ACSM1 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV54635505; called by muse, mutect2, varscan2
- ACSM2B | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV61657800; called by muse, mutect2, varscan2
- ACTN3 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.639); catalogued as COSV101557880; called by muse, mutect2, varscan2
- ADAM21 | c.2138C>T p.P713L | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV50792874; called by muse, mutect2, varscan2
- ADAMTSL3 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs774905636, COSV54446992; called by muse, mutect2, varscan2
- ADGRB3 | c.3184G>A p.A1062T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); catalogued as COSV53243642, COSV53260735; called by muse, mutect2, varscan2
- ADGRV1 | c.2368G>A p.E790K | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67983683; called by muse, mutect2, varscan2
- ADGRV1 | c.10765C>T p.P3589S | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV67983066; called by muse, mutect2, varscan2
- AJM1 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as rs1345272938, COSV56032924; called by muse, mutect2
- AKNA | c.506G>A p.R169K | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV99800968; called by muse, mutect2, varscan2
- AL645922.1 | c.1861C>T p.P621S | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT tolerated (0.78); PolyPhen benign (0.025); catalogued as COSV54960536; called by muse, mutect2, varscan2
- AMBP | c.333A>T p.K111N | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as COSV54323459; called by muse, mutect2, varscan2
- AMDHD1 | c.845G>A p.S282N | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57138687; called by muse, mutect2, varscan2
- ANKEF1 | c.1643+1G>A p.X548_splice | Splice Site (SNP) | VAF 11/44 reads (25%) | catalogued as COSV65692408, COSV65692455; called by muse, mutect2, varscan2
- ANKFN1 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 47/67 reads (70%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.24); catalogued as COSV59446793; called by muse, mutect2, varscan2
- ANPEP | c.1828G>A p.D610N | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1456553395, COSV55589443; called by muse, mutect2, varscan2
- APOL2 | c.493A>G p.T165A | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.036); catalogued as COSV50772076; called by muse, mutect2, varscan2
- APOO | c.237G>T p.Q79H | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64870506; called by muse, mutect2, varscan2
- ARHGAP9 | c.1802C>T p.S601F (on ENST00000393797 / NM_001319850.2; = p.S582F on NM_032496.4) | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57361626; called by muse, mutect2
- ASH1L | c.4183C>T p.P1395S | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.831); catalogued as COSV64207835; called by muse, mutect2, varscan2
- ASXL3 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52465259; called by muse, mutect2, varscan2
- ATMIN | c.1652A>G p.E551G | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV55146012; called by muse, mutect2, varscan2
- ATP10A | c.3400C>T p.P1134S | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1231534275, COSV63517063; called by muse, mutect2, varscan2
- ATP5F1C | c.626T>G p.V209G | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV59621576; called by muse, mutect2, varscan2
- ATP7B | c.1577G>A p.G526E | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54438219; called by muse, mutect2, varscan2
- B4GALNT3 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56752219; called by muse, mutect2, varscan2
- BAG4 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV54860069; called by muse, mutect2, varscan2
- BCOR | c.1577C>T p.S526L | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.53); PolyPhen benign (0.022); catalogued as rs778509267, COSV60704563, COSV60705549; called by muse, mutect2, varscan2
- BFSP2 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.877); catalogued as COSV56588698; called by muse, mutect2
- BRINP1 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV56299172; called by muse, mutect2, varscan2
- BRPF3 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.979); catalogued as COSV60207312; called by muse, mutect2, varscan2
- C2orf16 | c.5306C>T p.P1769L | Missense Mutation (SNP) | VAF 50/268 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1316703220, COSV62675427; called by muse, mutect2, varscan2
- C3AR1 | c.743G>A p.R248K | Missense Mutation (SNP) | VAF 4/102 reads (4%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as COSV50818695; called by muse, mutect2
- CACNA1I | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs1285437076, COSV60807702; called by muse, mutect2, varscan2
- CACNA1I | c.4927A>C p.K1643Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV60807723; called by muse, mutect2
- CAPN15 | c.920C>G p.T307S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as COSV54835829; called by muse, mutect2, varscan2
- CARD6 | c.2921C>T p.S974F | Missense Mutation (SNP) | VAF 75/281 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.135); catalogued as COSV54566103; called by muse, mutect2, varscan2
- CC2D1A | c.2059C>A p.P687T | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100528682; called by muse, mutect2, varscan2
- CCDC134 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.834); catalogued as COSV55387993; called by muse, mutect2, varscan2
- CCDC141 | c.3859T>A p.F1287I | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as COSV55373140; called by muse, mutect2, varscan2
- CCDC180 | c.2003A>G p.E668G | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as COSV63829931; called by muse, mutect2, varscan2
- CDC45 | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 76/181 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV54245211; called by muse, mutect2, varscan2
- CDH8 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV54865772; called by muse, varscan2
- CENPJ | c.2765C>G p.A922G | Missense Mutation (SNP) | VAF 69/133 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV101121509, COSV67883410; called by muse, mutect2, varscan2
- CEP104 | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 15/150 reads (10%) | catalogued as COSV65512270; called by muse, mutect2, varscan2
- CERS2 | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 19/97 reads (20%) | catalogued as rs779040680, COSV99645031; called by muse, mutect2, varscan2
- CFAP46 | c.7908C>A p.F2636L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.01); catalogued as COSV54152113; called by muse, mutect2
- CFAP47 | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 55/96 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52884290; called by muse, mutect2, varscan2
- CFAP61 | c.2375G>A p.R792K | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV55628505; called by muse, mutect2, varscan2
- CHD5 | c.832T>A p.F278I | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV52413979; called by muse, mutect2, varscan2
- CHD6 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 156/402 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV58556911; called by muse, mutect2, varscan2
- CHD9 | c.1432C>T p.H478Y | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV68298095; called by muse, mutect2, varscan2
- CHRNB3 | c.1054C>T p.H352Y | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.541); catalogued as COSV51494919; called by muse, mutect2, varscan2
- CILP | c.2555C>T p.P852L | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56024155; called by muse, mutect2, varscan2
- CKAP4 | c.1265C>T p.S422F | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV65172505; called by muse, mutect2, varscan2
- CLCN7 | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as COSV51970361; called by muse, mutect2, varscan2
- CNTFR | c.869G>A p.W290* | Nonsense Mutation (SNP) | VAF 33/114 reads (29%) | catalogued as COSV63633725; called by muse, mutect2, varscan2
- COBLL1 | c.398C>T p.P133L (on ENST00000392717; = p.P95L on NM_014900.5) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777984790, COSV52067477; called by muse, mutect2, varscan2
- COL12A1 | c.2921C>T p.S974L | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1308564004, COSV59395583; called by muse, mutect2, varscan2
- COL4A3 | c.3250G>A p.E1084K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV59258020; called by muse, mutect2, varscan2
- CSMD2 | c.4003A>C p.S1335R | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.644); catalogued as COSV53910162; called by muse, mutect2, varscan2
- CTAGE1 | c.1592C>T p.P531L | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV66943393; called by muse, mutect2, varscan2
- CYP2A13 | c.1304G>A p.G435E | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57837622; called by muse, mutect2, varscan2
- CYP3A43 | c.808G>T p.D270Y | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs775472541, COSV55936034; called by muse, mutect2, varscan2
- CYP4Z1 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs1206792114, COSV61964908; called by muse, mutect2, varscan2
- DACH1 | c.1081C>T p.Q361* | Nonsense Mutation (SNP) | VAF 65/268 reads (24%) | catalogued as COSV57498772; called by muse, mutect2, varscan2
- DAOA | c.392C>T p.T131I | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as rs956849335, COSV61602395; called by muse, mutect2, varscan2
- DCAF12L1 | c.27G>C p.R9S | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as COSV64421260, COSV64421750; called by muse, mutect2, varscan2
- DCANP1 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.32); catalogued as rs763417638, COSV72345811; called by muse, mutect2, varscan2
- DDO | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 28/60 reads (47%) | catalogued as rs751834179, COSV64470074; called by muse, mutect2, varscan2
- DEK | c.154C>T p.L52F | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV55237504, COSV99788995; called by muse, mutect2, varscan2
- DGKB | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as COSV51784425; called by muse, mutect2, varscan2
- DGKG | c.2254C>T p.P752S | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53964873; called by muse, mutect2, varscan2
- DHRS7C | c.726G>A p.W242* (on ENST00000330255 / NM_001220493.2; = p.W241* on NM_001105571.3) | Nonsense Mutation (SNP) | VAF 19/46 reads (41%) | catalogued as COSV57650677; called by muse, mutect2, varscan2
- DIAPH3 | c.1838C>T p.P613L (on ENST00000400324 / NM_001042517.2; = p.P350L on NM_030932.3) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV57369872; called by muse, mutect2
- DIPK2B | c.134G>A p.R45K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.003); catalogued as COSV65005238; called by muse, mutect2, varscan2
- DKKL1 | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 14/121 reads (12%) | catalogued as COSV55562316; called by muse, mutect2, varscan2
- DNAH10 | c.7717C>T p.P2573S (on ENST00000409039; = p.P2512S on NM_207437.3) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.523); catalogued as COSV101292605; called by muse, mutect2, varscan2
- DNAH10 | c.7718C>T p.P2573L (on ENST00000409039; = p.P2512L on NM_207437.3) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); catalogued as COSV101292607; called by muse, mutect2, varscan2
- DNAH8 | c.5452C>T p.R1818C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753290114, COSV59431946, COSV59443796; called by muse, mutect2, varscan2
- DNAJC6 | c.2420G>A p.R807K | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV54774493; called by muse, mutect2, varscan2
- DNTTIP1 | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.413); catalogued as COSV54754926; called by muse, mutect2, varscan2
- DPP6 | c.265C>T p.P89S (on ENST00000377770 / NM_001364500.2; = p.P27S on NM_001936.5) | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV59611746; called by muse, mutect2, varscan2
- DPYSL2 | c.1543C>T p.P515S | Missense Mutation (SNP) | VAF 48/275 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV60783269; called by muse, mutect2, varscan2
- DSG3 | c.2157G>A p.M719I | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1395179723, COSV57126108; called by muse, mutect2, varscan2
- DUOX1 | c.4010G>A p.R1337Q | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs779696519, COSV58486752; called by muse, mutect2, varscan2
- EARS2 | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV71942832; called by muse, mutect2, varscan2
- ECPAS | c.1987G>C p.G663R | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV52196739; called by muse, mutect2, varscan2
- EMID1 | c.279G>A p.W93* | Nonsense Mutation (SNP) | VAF 26/103 reads (25%) | catalogued as COSV61829336; called by muse, mutect2, varscan2
- ENDOU | c.691C>T p.L231F (on ENST00000422538 / NM_001172439.2; = p.L190F on NM_006025.4) | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1464856568, COSV57464988; called by muse, mutect2, varscan2
- EPHA5 | c.1601C>T p.S534L | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); catalogued as COSV56640181; called by muse, mutect2, varscan2
- EPHA6 | c.1648C>T p.Q550* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV67571242; called by muse, mutect2, varscan2
- EPHA6 | c.1781T>G p.V594G | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV101065206, COSV67571249; called by muse, mutect2
- EPHB1 | c.1763C>T p.S588F | Missense Mutation (SNP) | VAF 56/244 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.259); catalogued as COSV67660980; called by muse, mutect2, varscan2
- ETNPPL | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56595687; called by muse, mutect2, varscan2
- EYA2 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV57942712; called by muse, mutect2, varscan2
- EYA4 | c.781A>C p.T261P | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.419); catalogued as COSV62051507; called by muse, mutect2, varscan2
- EYS | c.1546G>A p.D516N | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs577044383, COSV60977174, COSV60983569; called by muse, mutect2, varscan2
- F2 | c.1299-1G>A p.X433_splice | Splice Site (SNP) | VAF 15/81 reads (19%) | catalogued as COSV100319363, COSV61315727; called by muse, mutect2, varscan2
- FAM135B | c.3677C>T p.S1226L | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as rs780775718, COSV52702552; called by muse, mutect2, varscan2
- FAM234B | c.1298C>T p.P433L | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.052); catalogued as rs746335872, COSV52194520; called by muse, mutect2, varscan2
- FBXO32 | c.673T>C p.F225L | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54890987; called by muse, mutect2, varscan2
- FGGY | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773592418, COSV58032714; called by muse, mutect2, varscan2
- FGL1 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs780353033, COSV67711900; called by muse, mutect2, varscan2
- FHDC1 | c.2422A>T p.M808L | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52599710; called by muse, mutect2, varscan2
- FKBP5 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as COSV61881597; called by muse, mutect2, varscan2
- FLG2 | c.6347G>A p.G2116E | Missense Mutation (SNP) | VAF 73/608 reads (12%) | SIFT tolerated (1); PolyPhen probably damaging (0.911); catalogued as rs766724042, COSV101166166; called by muse, mutect2, varscan2
- FLNA | c.4883C>T p.P1628L | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV61042622; called by muse, mutect2, varscan2
- FLRT2 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV58141059; called by muse, mutect2, varscan2
- FRRS1L | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV73746553; called by muse, mutect2, varscan2
- FUT5 | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs755213521, COSV53135810; called by muse, mutect2, varscan2
- GAB1 | c.1349T>A p.M450K | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53756483; called by muse, mutect2
- GALNTL6 | c.1013G>A p.G338E | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72490842; called by muse, mutect2, varscan2
- GCC2 | c.2762G>A p.R921K | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV59176190; called by muse, mutect2, varscan2
- GCM2 | c.238T>C p.S80P | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65275551; called by muse, mutect2, varscan2
- GCNT3 | c.643C>T p.Q215* | Nonsense Mutation (SNP) | VAF 25/159 reads (16%) | catalogued as COSV68532179; called by muse, mutect2, varscan2
- GFM1 | c.413T>C p.L138S | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51832615; called by muse, mutect2, varscan2
- GLIS1 | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV56548365; called by muse, mutect2, varscan2
- GLIS3 | c.2294C>T p.P765L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.997); catalogued as COSV60928613; called by muse, mutect2
- GML | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as COSV55277307; called by muse, mutect2, varscan2
- GNAT3 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV68068712; called by muse, mutect2
- GNAZ | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs189374840, COSV50737876; called by muse, mutect2, varscan2
- GPR137C | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV58704929; called by muse, mutect2, varscan2
- GPR139 | c.1055C>T p.S352F | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV58502798; called by muse, mutect2, varscan2
- GPR39 | c.1208G>A p.R403K | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV61416431, COSV61417197; called by muse, mutect2, varscan2
- GPRIN2 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV65400972; called by muse, mutect2
- GPRIN2 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782485720, COSV65400263, COSV65400709; called by muse, mutect2, varscan2
- GRAMD2A | c.375G>A p.V125= | Splice Region (SNP) | VAF 14/54 reads (26%) | catalogued as COSV59033540; called by muse, mutect2, varscan2
- GRM7 | c.925C>T p.L309F | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs1361389752, COSV63131778, COSV63152266; called by muse, mutect2, varscan2
- GSAP | c.1057C>T p.H353Y | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.28); catalogued as COSV57529867; called by muse, mutect2, varscan2
- GSDME | c.1382G>A p.R461K | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.054); catalogued as rs748383753, COSV56037980; called by muse, mutect2, varscan2
- GSTO2 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); catalogued as COSV58538417; called by muse, mutect2, varscan2
- GTF3C5 | c.638C>G p.P213R | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.153); catalogued as COSV59599866; called by muse, mutect2, varscan2
- GYS2 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV53923052; called by muse, mutect2
- HCLS1 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 87/299 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV57523881; called by muse, mutect2, varscan2
- HEATR4 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.758); catalogued as rs1366882631, COSV58572487; called by muse, mutect2, varscan2
- HIPK1 | c.2615G>A p.S872N | Missense Mutation (SNP) | VAF 83/160 reads (52%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.878); catalogued as COSV61247628; called by muse, mutect2, varscan2
- HLA-DOA | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 64/187 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as rs1188578062, COSV57714190; called by muse, mutect2
- HOMER1 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.86); PolyPhen benign (0.013); catalogued as rs894468923, COSV56526164; called by muse, mutect2, varscan2
- HOOK2 | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 9/74 reads (12%) | catalogued as COSV53402262; called by muse, mutect2, varscan2
- HOXA3 | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 60/188 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57826265; called by muse, mutect2, varscan2
- HOXB3 | c.965C>A p.P322H | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.315); catalogued as COSV57486737; called by muse, mutect2, varscan2
- HS3ST1 | c.567G>T p.K189N | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV50023597; called by muse, mutect2, varscan2
- HUNK | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.026); catalogued as COSV54228807; called by muse, mutect2, varscan2
- HYDIN | c.11066C>T p.S3689L | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1246004419, COSV66869397; called by muse, mutect2, varscan2
- IFIT5 | c.895C>T p.Q299* | Nonsense Mutation (SNP) | VAF 50/132 reads (38%) | catalogued as COSV65655554; called by muse, mutect2, varscan2
- IFT80 | c.1979C>T p.S660L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV58447354; called by muse, mutect2, varscan2
- IGSF1 | c.1981C>T p.H661Y | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.968); catalogued as COSV63837348; called by muse, mutect2, varscan2
- IKZF2 | c.1465C>T p.H489Y | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV59578043; called by muse, mutect2, varscan2
- IKZF4 | c.1436C>T p.P479L | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs1258599531, COSV100009324; called by muse, mutect2, varscan2
- IL1RL1 | c.1285G>T p.D429Y | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52115509; called by muse, mutect2, varscan2
- IMPDH1 | c.1507C>T p.H503Y (on ENST00000470772 / NM_001142573.2; = p.H589Y on NM_000883.4) | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58315964; called by muse, mutect2, varscan2
- INSRR | c.2966C>T p.S989F | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs745547166, COSV63872442, COSV63872945; called by muse, mutect2, varscan2
- IPCEF1 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs779344563, COSV99500397; called by muse, mutect2, varscan2
- IPCEF1 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0.1); catalogued as COSV99500398; called by muse, mutect2, varscan2
- KAT14 | c.1601C>T p.S534F | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV66607581; called by muse, mutect2, varscan2
- KCNA5 | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV52905514; called by muse, mutect2, varscan2
- KCNB1 | c.2120G>A p.G707E | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.186); catalogued as rs1457392474, COSV100870480, COSV100870571, COSV65568130; called by muse, mutect2, varscan2
- KCND3 | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV56180502; called by muse, mutect2, varscan2
- KCNG2 | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV60267723; called by muse, mutect2
- KCNK1 | c.86G>A p.G29D | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.769); catalogued as COSV64038057; called by muse, mutect2, varscan2
- KCNT2 | c.2242G>T p.E748* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as rs149408068, COSV99652495; called by muse, mutect2, varscan2
- KDM5B | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV99351341; called by muse, mutect2, varscan2
- KIAA0513 | c.838C>A p.P280T | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV50741157, COSV50741297; called by muse, mutect2
- KLHDC7A | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV68769683; called by muse, mutect2, varscan2
- KNL1 | c.2405C>T p.P802L (on ENST00000346991 / NM_170589.5; = p.P776L on NM_144508.5) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV61152414; called by muse, mutect2, varscan2
- KPRP | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV64221571; called by muse, mutect2, varscan2
- KRT26 | c.214C>T p.L72F | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.459); catalogued as COSV100053208, COSV56971693; called by muse, mutect2, varscan2
- LAMB4 | c.4139G>A p.G1380E | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as rs267601231, COSV52718565; called by muse, mutect2, varscan2
- LCT | c.3343G>T p.E1115* | Nonsense Mutation (SNP) | VAF 29/128 reads (23%) | catalogued as COSV51544352, COSV51548853; called by muse, mutect2, varscan2
- LIPG | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.719); catalogued as COSV54296116; called by muse, mutect2, varscan2
- LMX1A | c.1040A>T p.N347I | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV54220720; called by muse, varscan2
- LPO | c.-1G>A | Splice Region (SNP) | VAF 10/165 reads (6%) | catalogued as COSV51858615; called by muse, mutect2
- LRP1 | c.11774C>T p.S3925F | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.928); catalogued as COSV54503434; called by muse, mutect2, varscan2
- LRRIQ1 | c.3305G>A p.W1102* | Nonsense Mutation (SNP) | VAF 21/81 reads (26%) | catalogued as COSV67830359; called by muse, mutect2, varscan2
- LUC7L2 | c.601G>T p.D201Y | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54925866; called by muse, mutect2, varscan2
- LUZP2 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs1298627982, COSV61203370, COSV61217833; called by muse, mutect2, varscan2
- MAP1A | c.7571C>T p.S2524F | Missense Mutation (SNP) | VAF 69/193 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55808505; called by muse, mutect2, varscan2
- MAPK3 | c.305G>A p.G102D | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV53773310; called by muse, mutect2
- MARK1 | c.1563A>T p.K521N | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV65067399; called by muse, mutect2, varscan2
- MBD5 | c.1385C>T p.S462L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68696917; called by muse, mutect2, varscan2
- MDGA2 | c.2635G>C p.G879R (on ENST00000399232 / NM_001113498.2; = p.G581R on NM_182830.4) | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62091867; called by muse, mutect2, varscan2
- MDH1B | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs767858740, COSV65589025, COSV65589622; called by muse, mutect2, varscan2
- MED12L | c.963G>A p.M321I | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV56378114; called by muse, mutect2, varscan2
- MICB | c.1026G>C p.E342D | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.979); catalogued as COSV52856474, COSV52857199; called by muse, mutect2
- MIOX | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs769242335, COSV53312893; called by muse, mutect2, varscan2
- MKI67 | c.3394C>T p.P1132S | Missense Mutation (SNP) | VAF 138/323 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.28); catalogued as COSV64074241; called by muse, mutect2, varscan2
- MOSPD2 | c.1465C>T p.Q489* | Nonsense Mutation (SNP) | VAF 94/177 reads (53%) | catalogued as COSV66860025; called by muse, mutect2, varscan2
- MPZ | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0.022); catalogued as rs1383238492, COSV60667874, COSV60667989; ClinVar: uncertain significance; called by muse, mutect2
- MROH2B | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.223); catalogued as rs1030871074, COSV68183775; called by muse, mutect2, varscan2
- MTUS2 | c.1120G>A p.G374R | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.139); catalogued as rs199561946, COSV70916714; called by muse, mutect2, varscan2
- MUC13 | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV60699341; called by muse, mutect2
- MUC17 | c.3773C>T p.S1258F | Missense Mutation (SNP) | VAF 79/595 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.679); catalogued as rs1250892978, COSV60287898; called by muse, mutect2, varscan2
- MUC17 | c.13450C>T p.Q4484* | Nonsense Mutation (SNP) | VAF 13/77 reads (17%) | catalogued as COSV60287905; called by muse, mutect2, varscan2
- MUC20 | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1355305567, COSV57849583; called by muse, mutect2, varscan2
- MXRA5 | c.4464G>A p.M1488I | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV54234327; called by muse, mutect2, varscan2
- MYO15A | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as rs981927941, COSV52756314; called by muse, mutect2, varscan2
- MYO18B | c.7300G>A p.E2434K | Missense Mutation (SNP) | VAF 76/210 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as rs983088938, COSV59133748; called by muse, mutect2, varscan2
- MYO1A | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 9/56 reads (16%) | catalogued as COSV55653870; called by muse, mutect2, varscan2
- MYOM3 | c.3972-1G>A p.X1324_splice | Splice Site (SNP) | VAF 25/109 reads (23%) | catalogued as COSV58393562; called by muse, mutect2, varscan2
- NCOR1 | c.5533G>T p.E1845* | Nonsense Mutation (SNP) | VAF 23/109 reads (21%) | catalogued as COSV51973819, COSV51986045; called by muse, mutect2, varscan2
- NDNF | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.076); catalogued as COSV65633372; called by muse, mutect2, varscan2
- NELL2 | c.836C>G p.T279S | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.051); catalogued as COSV61574341, COSV61584951; called by muse, mutect2, varscan2
- NEU4 | c.1259C>G p.S420C (on ENST00000391969 / NM_001167602.3; = p.S432C on NM_080741.4) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57990296; called by muse, mutect2, varscan2
- NEURL4 | c.3238G>A p.G1080S | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs745944848, COSV59748304; called by muse, mutect2, varscan2
- NIPA1 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV61679875; called by muse, mutect2
- NMBR | c.734A>T p.N245I | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV99237501; called by muse, mutect2, varscan2
- NMI | c.706T>G p.S236A | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV54638133; called by muse, mutect2, varscan2
- NOBOX | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV56194241; called by muse, mutect2, varscan2
- NOS1 | c.2593G>A p.D865N | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs200664091, COSV57611896; called by muse, mutect2, varscan2
- NOS1 | c.2239G>A p.A747T | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.972); catalogued as COSV57611906; called by muse, mutect2, varscan2
- NOS1 | c.1524G>A p.E508= | Splice Region (SNP) | VAF 15/166 reads (9%) | catalogued as COSV57611917, COSV57623629; called by muse, mutect2
- NOS1 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.795); catalogued as COSV57611927; called by muse, mutect2
- NPAP1 | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV61506741; called by muse, mutect2, varscan2
- NR3C2 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as rs1334509971, COSV60990075; called by muse, mutect2
- NRK | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.845); catalogued as rs751406404, COSV54599088, COSV99686747; called by muse, varscan2
- NRK | c.1160G>A p.G387E | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as COSV54595915, COSV99686618; called by muse, varscan2
- OAS3 | c.2405G>A p.G802D | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1331938194, COSV57445591; called by muse, mutect2, varscan2
- OBSCN | c.13432A>T p.S4478C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as COSV52772025; called by muse, mutect2, varscan2
- OBSCN | c.21430C>T p.P7144S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV62363290; called by muse, mutect2, varscan2
- OR4F17 | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 63/315 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV58841952; called by muse, mutect2, varscan2
- OR51T1 | c.217C>A p.L73I | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV59025290; called by muse, mutect2, varscan2
- OR6B1 | c.765C>A p.F255L | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV68770003, COSV68770112; called by muse, mutect2, varscan2
- OR8H2 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV57944052; called by muse, mutect2, varscan2
- OTUD7B | c.2321C>T p.S774F | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.363); catalogued as COSV64916063; called by muse, mutect2, varscan2
- OVCH1 | c.2417G>A p.W806* | Nonsense Mutation (SNP) | VAF 37/93 reads (40%) | catalogued as COSV58962573; called by muse, mutect2, varscan2
- PALLD | c.1843C>T p.P615S | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.073); catalogued as rs1454111307, COSV54980085; called by muse, mutect2, varscan2
- PALMD | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as COSV54164336; called by muse, mutect2, varscan2
- PAPPA2 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as rs866461390, COSV62773209, COSV62780685; called by muse, mutect2, varscan2
- PATJ | c.2533G>A p.E845K | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV57161636; called by muse, mutect2, varscan2
- PAX1 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752485368, COSV68271822; called by muse, mutect2, varscan2
- PAX6 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53793287; called by muse, mutect2, varscan2
- PCDH17 | c.742T>C p.Y248H | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64973849; called by muse, mutect2, varscan2
- PCDH17 | c.3017G>A p.R1006Q | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.271); catalogued as rs866221250, COSV64973854; called by muse, mutect2, varscan2
- PCDHA4 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.551); catalogued as COSV63541201; called by muse, mutect2, varscan2
- PCDHB12 | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53396393; called by muse, mutect2, varscan2
- PCED1B | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 22/82 reads (27%) | catalogued as COSV71395179; called by muse, mutect2, varscan2
- PCNX3 | c.4648T>G p.F1550V | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV63136677; called by muse, mutect2, varscan2
- PDS5A | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57824404; called by muse, mutect2, varscan2
- PGLS | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV53114442; called by muse, mutect2, varscan2
- PITRM1 | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56531136; called by muse, mutect2, varscan2
- PKN3 | c.1357G>A p.A453T | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV52576565; called by muse, mutect2, varscan2
- PLA2G3 | c.1199+1G>A p.X400_splice | Splice Site (SNP) | VAF 9/36 reads (25%) | catalogued as COSV53209299; called by muse, mutect2, varscan2
- PLA2G3 | c.768G>A p.W256* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as rs777224568, COSV53209324; called by muse, mutect2, varscan2
- PLA2G4A | c.1544C>T p.S515F | Missense Mutation (SNP) | VAF 70/232 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV66553652; called by muse, mutect2, varscan2
- PLA2G4D | c.572G>A p.G191E | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV51819583; called by muse, mutect2, varscan2
- PLCB2 | c.1695C>T p.A565= | Splice Region (SNP) | VAF 4/20 reads (20%) | catalogued as COSV53033364; called by muse, mutect2
- PLCH1 | c.3767C>T p.P1256L (on ENST00000340059 / NM_001130960.2; = p.P1248L on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.031); catalogued as rs187476467, COSV58196425; called by muse, mutect2, varscan2
- PLCL2 | c.1981C>T p.P661S (on ENST00000615277 / NM_001144382.2; = p.P535S on NM_015184.5) | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV67622030; called by muse, mutect2, varscan2
- PLPBP | c.416T>C p.L139S | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60239644; called by muse, mutect2, varscan2
- PMS1 | c.2712G>A p.M904I | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV59716349; called by muse, mutect2
- POU2F3 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 65/213 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV52793760; called by muse, mutect2, varscan2
- PPM1E | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 52/89 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV57574083; called by muse, mutect2, varscan2
- PPP4R1 | c.2038C>T p.R680* (on ENST00000400556 / NM_001042388.3; = p.R663* on NM_005134.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 17/114 reads (15%) | catalogued as rs776245392, COSV53281685; called by muse, mutect2, varscan2
- PPP6R3 | c.769C>T p.H257Y | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV55726147; called by muse, mutect2, varscan2
- PRAG1 | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as COSV58160671; called by muse, mutect2, varscan2
- PRDX1 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs915069689, COSV53113686; called by muse, mutect2, varscan2
- PREX2 | c.2132C>T p.A711V | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.381); catalogued as rs775153592, COSV55768476; called by muse, mutect2, varscan2
- PRKAA2 | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); catalogued as COSV64803633; called by muse, mutect2, varscan2
- PRODH2 | c.1062+1G>A p.X354_splice (on ENST00000301175; = p.X278_splice on NM_021232.2 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 10/54 reads (19%) | catalogued as rs757540122, COSV56559750; called by muse, mutect2, varscan2
- PRPSAP1 | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61211061; called by muse, mutect2, varscan2
- PSG11 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 94/200 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV60455140; called by muse, mutect2, varscan2
- PTCH2 | c.2554C>T p.P852S | Missense Mutation (SNP) | VAF 62/227 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.066); catalogued as COSV64711021; called by muse, mutect2, varscan2
- PTCHD3 | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.196); catalogued as COSV71256767; called by muse, mutect2, varscan2
- PTPN5 | c.1055C>T p.S352F | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62125826; called by muse, mutect2, varscan2
- PTPRA | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53781462; called by muse, mutect2, varscan2
- RAD51C | c.1033G>A p.G345R | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100507093; called by muse, mutect2, varscan2
- RAI1 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.177); catalogued as COSV55392700; called by muse, mutect2, varscan2
- RASAL1 | c.485G>A p.W162* | Nonsense Mutation (SNP) | VAF 4/13 reads (31%) | catalogued as rs1203040302, COSV55655806; called by muse, mutect2, varscan2
- RBMS3 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV56143832, COSV56167831; called by muse, mutect2, varscan2
- RBPJL | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV59213571; called by muse, mutect2, varscan2
- RELCH | c.1220C>T p.P407L | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV56885289; called by muse, mutect2, varscan2
- RERGL | c.541A>T p.K181* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as COSV57461879; called by muse, mutect2, varscan2
- RNF40 | c.1660C>T p.P554S | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV61214754; called by muse, mutect2, varscan2
- RPTOR | c.3076C>T p.P1026S | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as COSV100157106; called by muse, mutect2, varscan2
- RUVBL2 | c.412A>G p.I138V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV55485108; called by muse, mutect2, varscan2
- SEL1L3 | c.953G>A p.G318D | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.587); catalogued as COSV53540497, COSV53546657; called by muse, mutect2, varscan2
- SEMA5B | c.2180C>T p.S727F | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.797); catalogued as rs1205387351, COSV52097239; called by muse, mutect2, varscan2
- SERPINA9 | c.236T>C p.L79P | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54074651; called by muse, mutect2, varscan2
- SERPINB3 | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52191542; called by muse, mutect2, varscan2
- SERPINE2 | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV51457435; called by muse, mutect2, varscan2
- SH2D3C | c.1225C>T p.P409S (on ENST00000314830 / NM_170600.3; = p.P252S on NM_005489.4) | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.821); catalogued as COSV59122391; called by muse, mutect2, varscan2
- SHANK3 | c.4001C>T p.P1334L | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.306); catalogued as COSV53186354; called by muse, mutect2
- SIGLEC5 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.356); catalogued as rs764529624, COSV55781271; called by muse, mutect2, varscan2
- SIRPB1 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs754682510, COSV53538614; called by muse, mutect2, varscan2
- SIRPB2 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.82); PolyPhen benign (0.009); catalogued as rs751161092, COSV63123725; called by muse, mutect2, varscan2
- SLC12A1 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.196); catalogued as COSV57709427; called by muse, mutect2, varscan2
- SLC22A15 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs767735362, COSV65680152, COSV65680535; called by muse, mutect2, varscan2
- SLC25A19 | c.542C>A p.T181N | Missense Mutation (SNP) | VAF 28/275 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57467617; called by muse, mutect2, varscan2
- SLC43A2 | c.1540C>T p.P514S | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100025229, COSV56769075; called by muse, mutect2, varscan2
- SLC6A3 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV54364087; called by muse, mutect2, varscan2
- SLC8A1 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.814); catalogued as rs759353126, COSV100247466, COSV60479878; called by muse, mutect2, varscan2
- SPEG | c.9232G>A p.G3078S | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.024); catalogued as rs200692984; called by muse, mutect2, varscan2
- SPTBN1 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV61688416; called by muse, mutect2, varscan2
- ST18 | c.806G>A p.G269D | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1343418485, COSV99390898; called by muse, mutect2, varscan2
- ST18 | c.805G>A p.G269S | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99390899; called by muse, mutect2, varscan2
- ST6GAL2 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 4/8 reads (50%) | PolyPhen possibly damaging (0.728); catalogued as rs1443893427, COSV64528114; called by muse, mutect2, varscan2
- STRN4 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 37/145 reads (26%) | catalogued as COSV99623998; called by muse, mutect2, varscan2
- STXBP5L | c.1363C>T p.L455F | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.623); catalogued as COSV56507394, COSV56512497; called by muse, mutect2, varscan2
- SV2C | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV59219607; called by muse, mutect2
- SV2C | c.1879C>T p.L627F | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV59226171; called by muse, mutect2, varscan2
- SYNPO | c.2110C>T p.R704C (on ENST00000394243 / NM_001166208.2; = p.R460C on NM_007286.6) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs755694682, COSV56940059; called by muse, mutect2, varscan2
- TACC3 | c.2422C>T p.Q808* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as COSV100508913; called by muse, mutect2, varscan2
- TAF1 | c.1541C>T p.S514F (on ENST00000373790 / NM_138923.4; = p.S535F on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV52112683; called by muse, mutect2, varscan2
- TAS2R16 | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 49/182 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV50797088, COSV50799254; called by muse, mutect2, varscan2
- TCF20 | c.3935C>T p.P1312L | Missense Mutation (SNP) | VAF 34/224 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs754421645, COSV100166912; called by muse, mutect2, varscan2
- TCF20 | c.3934C>T p.P1312S | Missense Mutation (SNP) | VAF 34/221 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV100166915; called by muse, mutect2, varscan2
- THSD4 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs761670963, COSV55962826; called by muse, mutect2, varscan2
- THSD7B | c.3316G>A p.D1106N (on ENST00000272643; = p.D1104N on NM_001316349.2) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV55683616; called by muse, mutect2, varscan2
- THSD7B | c.4618G>A p.D1540N (on ENST00000272643; = p.D1538N on NM_001316349.2) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV55662655; called by muse, mutect2, varscan2
- TIGIT | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs146935299; called by muse, mutect2, varscan2
- TLR4 | c.332G>C p.G111A (on ENST00000355622 / NM_138554.5; = p.G71A on NM_003266.4) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.903); catalogued as COSV100790657, COSV62922591, COSV62923206; called by muse, mutect2, varscan2
- TLX3 | c.118G>T p.G40C | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.879); catalogued as rs765665907, COSV51539877; called by muse, mutect2, varscan2
- TMC7 | c.1687C>T p.L563F | Missense Mutation (SNP) | VAF 91/460 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV58583420; called by muse, mutect2, varscan2
- TMEM132D | c.2110A>G p.K704E | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV67160289; called by muse, mutect2
- TMEM266 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66379442; called by muse, mutect2, varscan2
- TOR1AIP1 | c.1664A>T p.D555V | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54869556; called by muse, mutect2, varscan2
- TRHDE | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV53843477; called by muse, mutect2, varscan2
- TRIM22 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.325); catalogued as COSV66090740; called by muse, mutect2, varscan2
- TRPC1 | c.1463A>T p.D488V (on ENST00000476941 / NM_001251845.2; = p.D454V on NM_003304.4) | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.309); catalogued as COSV56425089; called by muse, mutect2, varscan2
- TSPO2 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs756823502, COSV55109906; called by muse, mutect2, varscan2
- TTC6 | c.6G>A p.M2I (on ENST00000267368; = p.M1271I on NM_001310135.3) | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV57448728; called by muse, mutect2, varscan2
- TTN | c.35003A>C p.K11668T (on ENST00000591111; = p.K10741T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/94 reads (20%) | PolyPhen benign (0.116); catalogued as rs1266419307, COSV60042692; called by muse, mutect2, varscan2
- TTN | c.31357G>A p.E10453K (on ENST00000591111; = p.E9526K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/86 reads (14%) | PolyPhen probably damaging (0.953); catalogued as COSV59933660; called by muse, mutect2, varscan2
- TTN | c.4077A>C p.E1359D (on ENST00000591111; = p.E1313D on NM_003319.4) | Missense Mutation (SNP) | VAF 6/53 reads (11%) | PolyPhen probably damaging (0.99); catalogued as COSV60042736; called by muse, mutect2, varscan2
- UBE4A | c.1177C>T p.P393S (on ENST00000252108 / NM_001204077.2; = p.P400S on NM_004788.4) | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.185); catalogued as COSV52804073; called by muse, mutect2, varscan2
- UBN2 | c.1962G>A p.W654* | Nonsense Mutation (SNP) | VAF 28/62 reads (45%) | catalogued as COSV56030086; called by muse, mutect2, varscan2
- UNC79 | c.6758G>A p.R2253Q (on ENST00000393151 / NM_001346218.2; = p.R2076Q on NM_020818.5) | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56386886; called by muse, mutect2, varscan2
- UNC80 | c.868C>T p.H290Y | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.039); catalogued as rs1466542411, COSV55890805; called by muse, mutect2, varscan2
- USH2A | c.11320G>A p.E3774K | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV56330825, COSV56366177; called by muse, mutect2
- USP48 | c.938C>T p.T313I | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV57609699; called by muse, mutect2, varscan2
- VGLL3 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV67352969; called by muse, mutect2
- VIM | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.391); catalogued as COSV56405744; called by muse, mutect2, varscan2
- VPS35 | c.1576C>T p.R526C | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs398124658, CM144911, COSV54478592; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR37 | c.1400C>T p.P467L | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV54128714; called by muse, mutect2, varscan2
- ZBTB14 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs962156159, COSV63696242; called by muse, mutect2
- ZBTB32 | c.1438T>G p.C480G | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV52890460; called by muse, mutect2, varscan2
- ZC3H7A | c.547C>T p.L183F | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV63269528; called by muse, mutect2, varscan2
- ZDHHC4 | c.662T>G p.V221G | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV60106472; called by muse, mutect2, varscan2
- ZFHX3 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV51717819; called by muse, mutect2, varscan2
- ZIC1 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV51552302; called by muse, mutect2
- ZNF277 | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV100702582, COSV62464212; called by muse, mutect2, varscan2
- ZNF350 | c.517C>T p.H173Y | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.02); catalogued as COSV54708660; called by muse, mutect2, varscan2
- ZNF536 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.546); catalogued as COSV62823756; called by muse, mutect2, varscan2
- ZNFX1 | c.3769G>T p.G1257C | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65597222, COSV65598417; called by muse, mutect2, varscan2
- DDX3X | c.103+3_103+7del | Splice Region (DEL) | VAF 20/33 reads (61%) | called by mutect2, pindel, varscan2
- DNM1 | c.675_677delinsTT p.P226Sfs*10 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | called by pindel, varscan2*
- FCGBP | c.1494G>A p.M498I | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MAGEB6B | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- PRAMEF7 | c.1220G>C p.S407T | Missense Mutation (SNP) | VAF 55/307 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- AADACL4 | c.915C>T p.G305= | Silent (SNP) | VAF 83/193 reads (43%) | catalogued as COSV66106228; called by muse, mutect2, varscan2
- ACTL8 | c.336G>A p.K112= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV64861368; called by muse, mutect2, varscan2
- ADAM33 | c.1938C>A p.A646= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as COSV62934646; called by muse, mutect2, varscan2
- AGBL1 | c.1389G>A p.P463= | Silent (SNP) | VAF 50/129 reads (39%) | catalogued as rs751128989, COSV66850235; called by muse, mutect2, varscan2
- AL592490.1 | c.1035G>A p.V345= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as COSV69424616; called by muse, mutect2, varscan2
- ALPG | c.219C>T p.I73= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as COSV54965994; called by muse, mutect2, varscan2
- APOL4 | c.753G>A p.R251= (on ENST00000352371 / NM_145660.2; = p.R248= on NM_030643.4) | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV60654516; called by muse, mutect2, varscan2
- ARAP2 | c.3097A>C p.R1033= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV100395182; called by muse, mutect2, varscan2
- ATP6V1C1 | c.150C>T p.V50= | Silent (SNP) | VAF 43/131 reads (33%) | catalogued as rs375980479; called by muse, mutect2, varscan2
- ATP9B | c.2553C>T p.P851= | Silent (SNP) | VAF 36/95 reads (38%) | catalogued as COSV56950839; called by muse, mutect2, varscan2
- C15orf39 | c.438G>C p.L146= | Silent (SNP) | VAF 5/65 reads (8%) | catalogued as COSV62296611; called by muse, mutect2
- CAPRIN2 | c.2460A>G p.R820= | Silent (SNP) | VAF 28/138 reads (20%) | catalogued as COSV51832444; called by muse, mutect2, varscan2
- CC2D1A | c.2058C>T p.F686= | Silent (SNP) | VAF 26/175 reads (15%) | catalogued as COSV100528681; called by muse, mutect2, varscan2
- CD163 | c.3195C>T p.F1065= | Silent (SNP) | VAF 50/138 reads (36%) | catalogued as rs763870346, COSV63129316; called by muse, mutect2, varscan2
- CD93 | c.1647C>T p.I549= | Silent (SNP) | VAF 36/123 reads (29%) | catalogued as rs1323075425, COSV55665017; called by muse, mutect2, varscan2
- CDH8 | c.1398C>T p.I466= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as rs962868929, COSV54865781, COSV54890393; called by muse, varscan2
- CERS2 | c.399C>T p.F133= | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as rs1455134209, COSV99645773; called by muse, mutect2, varscan2
- CERS6 | c.390G>A p.T130= | Silent (SNP) | VAF 16/117 reads (14%) | catalogued as rs372372722; called by muse, mutect2, varscan2
- CHRDL2 | c.798C>T p.H266= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV55222718; called by muse, mutect2, varscan2
- CHST12 | c.759C>T p.S253= | Silent (SNP) | VAF 21/140 reads (15%) | catalogued as COSV51674685; called by muse, mutect2, varscan2
- CILP | c.993G>A p.K331= | Silent (SNP) | VAF 8/93 reads (9%) | catalogued as rs778553313, COSV56024163; called by muse, mutect2, varscan2
- CNTNAP5 | c.483C>A p.P161= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs191027725, COSV70485009; called by muse, mutect2, varscan2
- COL5A1 | c.825C>T p.Y275= | Silent (SNP) | VAF 66/189 reads (35%) | catalogued as rs771253587, COSV65666294; ClinVar: likely benign; called by muse, mutect2, varscan2
- COMMD4 | c.553C>T p.L185= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as rs774000839, COSV51190407; called by muse, mutect2, varscan2
- CORO1C | c.897C>T p.S299= | Silent (SNP) | VAF 38/110 reads (35%) | catalogued as COSV54595747; called by muse, mutect2, varscan2
- CPXM1 | c.2094C>T p.F698= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as rs766761505, COSV66044544; called by muse, mutect2, varscan2
- CSMD3 | c.7875T>A p.P2625= (on ENST00000297405 / NM_001363185.1; = p.P2521= on NM_052900.3) | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV52174140; called by muse, mutect2, varscan2
- CYB5RL | c.552C>T p.L184= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV55277300; called by muse, mutect2, varscan2
- CYP4F12 | c.1029C>T p.N343= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV61173707; called by muse, mutect2, varscan2
- CYP4F22 | c.984A>G p.E328= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV54108275; called by muse, mutect2, varscan2
- DEFB124 | c.21C>T p.F7= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as COSV52428104; called by muse, mutect2, varscan2
- DENND2C | c.717A>G p.E239= | Silent (SNP) | VAF 32/63 reads (51%) | catalogued as COSV67921637; called by muse, mutect2, varscan2
- DGLUCY | c.1597C>T p.L533= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as rs1005484790, COSV56366195; called by muse, mutect2, varscan2
- DNAH2 | c.5400C>T p.S1800= | Silent (SNP) | VAF 31/73 reads (42%) | catalogued as COSV66719282; called by muse, mutect2, varscan2
- DNER | c.510G>A p.Q170= | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as COSV59165765; called by muse, mutect2, varscan2
- DRD3 | c.1038C>T p.F346= | Silent (SNP) | VAF 56/234 reads (24%) | catalogued as COSV55680097; called by muse, mutect2, varscan2
- DRD3 | c.135C>T p.F45= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as rs201146268, COSV55679040; called by muse, mutect2, varscan2
- DUOX1 | c.4011G>A p.R1337= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV100368420; called by muse, mutect2, varscan2
- DYNC2H1 | c.9111C>T p.F3037= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV62093643; called by muse, mutect2, varscan2
- ELF3 | c.45C>T p.F15= | Silent (SNP) | VAF 45/166 reads (27%) | catalogued as COSV62838238, COSV62840231; called by muse, mutect2, varscan2
- ELP3 | c.1339T>C p.L447= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV56459045; called by muse, mutect2
- EML5 | c.654G>A p.G218= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as rs1439368049, COSV100716134; called by muse, mutect2, varscan2
- ESYT1 | c.1597C>T p.L533= | Silent (SNP) | VAF 29/263 reads (11%) | catalogued as COSV57272844; called by muse, mutect2
- FASTKD5 | c.1530C>T p.L510= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV53905960; called by muse, mutect2, varscan2
- FERMT3 | c.1068C>G p.L356= | Silent (SNP) | VAF 50/131 reads (38%) | catalogued as COSV54179385; called by muse, mutect2, varscan2
- FGF8 | c.576C>T p.F192= (on ENST00000344255 / NM_033164.4; = p.F174= on NM_006119.6) | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV60142813; called by muse, mutect2, varscan2
- FGFR1 | c.1392G>A p.E464= (on ENST00000447712 / NM_023110.3; = p.E462= on NM_015850.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/126 reads (20%) | catalogued as COSV58334036; called by muse, mutect2, varscan2
- FGFR2 | c.2310G>A p.L770= | Silent (SNP) | VAF 23/130 reads (18%) | catalogued as COSV60646674; called by muse, mutect2, varscan2
- FGFR4 | c.69G>A p.E23= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV52803377; called by muse, mutect2, varscan2
- FLG2 | c.6348G>A p.G2116= | Silent (SNP) | VAF 74/613 reads (12%) | catalogued as rs763358896, COSV101166165; called by muse, mutect2, varscan2
- GAB1 | c.1347A>G p.P449= | Silent (SNP) | VAF 37/103 reads (36%) | catalogued as rs780650312, COSV53756468; called by muse, mutect2
- GABRB1 | c.828C>T p.V276= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs778588040, COSV54972251, COSV54998831; called by muse, mutect2, varscan2
- GATA2 | c.1344C>T p.H448= | Silent (SNP) | VAF 62/135 reads (46%) | catalogued as COSV62004245; called by muse, mutect2, varscan2
- GDF5 | c.1332G>A p.T444= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as rs529197082, COSV65499041; called by muse, mutect2, varscan2
- GEM | c.618G>A p.G206= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV52597310; called by muse, mutect2, varscan2
- GGT6 | c.1068G>A p.V356= (on ENST00000574154 / NM_001122890.3; = p.V324= on NM_153338.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV54597487; called by muse, mutect2, varscan2
- GPR153 | c.816C>T p.D272= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs148652706; called by muse, mutect2, varscan2
- GRIN2B | c.4347G>A p.G1449= | Silent (SNP) | VAF 39/142 reads (27%) | catalogued as COSV74205834; called by muse, mutect2, varscan2
- GUCA1B | c.201G>A p.K67= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV57835229, COSV57835857; called by muse, mutect2, varscan2
- H2AC1 | c.15G>A p.G5= | Silent (SNP) | VAF 26/154 reads (17%) | catalogued as rs770804341, COSV51236763; called by muse, mutect2, varscan2
- HNF4A | c.435G>A p.E145= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs772959288, COSV57382634; ClinVar: benign; called by muse, mutect2, varscan2
- HTR3C | c.1170G>A p.G390= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV59175189; called by muse, mutect2
- IKZF4 | c.1437C>T p.P479= | Silent (SNP) | VAF 25/45 reads (56%) | catalogued as COSV100009326; called by muse, mutect2, varscan2
- IKZF4 | c.1734C>T p.V578= | Silent (SNP) | VAF 39/344 reads (11%) | catalogued as rs1191204797, COSV56268213; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1335C>T p.I445= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as COSV61156207; called by muse, mutect2, varscan2
- IL3 | c.183G>A p.G61= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs1348316046, COSV57308933; called by muse, mutect2, varscan2
- INAVA | c.1587C>T p.P529= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV66256523; called by mutect2, varscan2
- INTS1 | c.3627G>A p.S1209= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as rs1157649357, COSV67177375; called by muse, mutect2, varscan2
- ISLR | c.564C>T p.I188= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs138253214, COSV51433161, COSV51435233; called by muse, mutect2, varscan2
- ISLR | c.1281C>T p.S427= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV51433728; called by muse, mutect2, varscan2
- KANK2 | c.1098C>T p.A366= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs1190011489, COSV62007846; called by muse, mutect2, varscan2
- KCTD16 | c.123C>T p.S41= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV72578645; called by muse, mutect2, varscan2
- KDM5B | c.84T>G p.P28= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV99351339; called by muse, mutect2, varscan2
- KIF21B | c.1896C>T p.F632= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as COSV59757339; called by muse, mutect2, varscan2
- KLF4 | c.411G>A p.S137= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV65928912; called by muse, mutect2
- KRT28 | c.301C>T p.L101= | Silent (SNP) | VAF 15/125 reads (12%) | catalogued as COSV60685069; called by muse, mutect2, varscan2
- KRT76 | c.1335C>T p.A445= | Silent (SNP) | VAF 21/108 reads (19%) | catalogued as COSV60120142; called by muse, mutect2, varscan2
- KRTAP12-3 | c.69C>T p.S23= | Silent (SNP) | VAF 65/184 reads (35%) | catalogued as COSV59961396; called by muse, mutect2, varscan2
- LATS2 | c.1533G>T p.R511= | Silent (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- LMNB2 | c.678C>T p.F226= | Silent (SNP) | VAF 18/111 reads (16%) | catalogued as rs182026397, COSV57587943; called by muse, mutect2, varscan2
- LMNTD2 | c.663C>T p.A221= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV54241037; called by muse, mutect2, varscan2
- LRP2 | c.2145C>T p.S715= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV55552337; called by muse, mutect2, varscan2
- LRP4 | c.708C>T p.F236= | Silent (SNP) | VAF 45/215 reads (21%) | catalogued as COSV66135710; called by muse, mutect2, varscan2
- LRRN1 | c.537G>A p.L179= | Silent (SNP) | VAF 22/102 reads (22%) | catalogued as COSV60013749; called by muse, mutect2
- LTA | c.432C>T p.F144= | Silent (SNP) | VAF 60/198 reads (30%) | catalogued as COSV69304611; called by muse, mutect2, varscan2
- MAGEC1 | c.852C>T p.F284= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as COSV53567997, COSV99595854; called by muse, varscan2
- MEN1 | c.1845C>A p.L615= | Silent (SNP) | VAF 50/143 reads (35%) | catalogued as COSV53643080; called by muse, mutect2, varscan2
- MICAL3 | c.897C>T p.F299= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs751823263, COSV52891604; called by muse, mutect2, varscan2
- MORC1 | c.51C>T p.F17= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs1324985399, COSV51714699; called by muse, mutect2
- MUC16 | c.29340C>T p.T9780= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs772669572, COSV67464273; called by muse, mutect2, varscan2
- MYOM1 | c.183C>T p.F61= | Silent (SNP) | VAF 38/86 reads (44%) | catalogued as COSV55291389; called by muse, mutect2, varscan2
- NMBR | c.735T>C p.N245= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV99237500; called by muse, mutect2, varscan2
- NUP214 | c.5193C>T p.V1731= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as COSV63909441; called by muse, mutect2, varscan2
- NXPE4 | c.267C>T p.T89= | Silent (SNP) | VAF 30/124 reads (24%) | catalogued as rs1398114645, COSV64943750; called by muse, mutect2, varscan2
- ODF4 | c.171C>A p.S57= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV60272085; called by muse, mutect2, varscan2
- OR12D2 | c.726C>T p.S242= | Silent (SNP) | VAF 28/162 reads (17%) | catalogued as COSV65827812; called by muse, mutect2, varscan2
- OR1I1 | c.531C>T p.F177= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as rs760677097, COSV52917947; called by muse, mutect2, varscan2
- OR1I1 | c.933C>T p.P311= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs1352635415, COSV52917961; called by muse, mutect2
- OR2M5 | c.306C>T p.F102= | Silent (SNP) | VAF 147/470 reads (31%) | catalogued as rs1558236298, COSV63546222; called by muse, mutect2, varscan2
- OR6C1 | c.459C>T p.I153= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV65573357; called by muse, mutect2
- OR7G1 | c.78C>T p.I26= | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as rs761369127, COSV53317668; called by muse, mutect2, varscan2
- PARD3B | c.2511G>A p.T837= (on ENST00000406610 / NM_001302769.2; = p.T768= on NM_057177.7) | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as rs750239561, COSV62510096; called by muse, mutect2, varscan2
- PCDHA1 | c.1260C>T p.V420= | Silent (SNP) | VAF 55/213 reads (26%) | catalogued as COSV65374204; called by muse, mutect2, varscan2
- PCDHA13 | c.1938C>T p.R646= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as rs1554181328, COSV56499074; called by muse, mutect2, varscan2
- PKHD1 | c.4908G>A p.L1636= | Silent (SNP) | VAF 32/102 reads (31%) | catalogued as COSV61874375; called by muse, mutect2, varscan2
- PLEKHG4 | c.3030C>T p.S1010= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs1199348181, COSV58572793; called by muse, mutect2, varscan2
- PLGRKT | c.240C>T p.F80= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV56350103; called by muse, mutect2, varscan2
- PLXNB2 | c.5112C>T p.V1704= | Silent (SNP) | VAF 46/186 reads (25%) | catalogued as COSV63781567; called by muse, mutect2, varscan2
- POLR3D | c.1086C>T p.S362= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs770938510, COSV60571132; called by muse, mutect2, varscan2
- PRAMEF18 | c.91C>T p.L31= | Silent (SNP) | VAF 53/512 reads (10%) | called by muse, mutect2
- PTPRA | c.1476C>T p.V492= | Silent (SNP) | VAF 31/202 reads (15%) | catalogued as rs1472375235, COSV53781478; called by muse, mutect2, varscan2
- PTPRN2 | c.2526C>T p.I842= | Silent (SNP) | VAF 37/76 reads (49%) | catalogued as rs759623053, COSV66104780; called by muse, mutect2, varscan2
- PTPRU | c.2245C>T p.L749= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV60527474; called by muse, mutect2, varscan2
- PUS10 | c.154C>T p.L52= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV57452193; called by muse, mutect2, varscan2
- PWWP3A | c.246C>T p.P82= (on ENST00000627377; = p.P81= on NM_032853.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 4/59 reads (7%) | catalogued as COSV60902175; called by muse, mutect2
- RAD51C | c.1032G>A p.Q344= | Silent (SNP) | VAF 11/15 reads (73%) | catalogued as rs876658609, COSV100507092; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- RDH16 | c.240G>A p.V80= | Silent (SNP) | VAF 67/150 reads (45%) | catalogued as COSV62458109; called by muse, mutect2, varscan2
- RET | c.1341C>T p.A447= | Silent (SNP) | VAF 29/147 reads (20%) | catalogued as rs876659737, COSV60693823; ClinVar: likely benign; called by muse, mutect2, varscan2
- RIMS3 | c.321C>T p.S107= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV65504408; called by muse, mutect2, varscan2
- RNF213 | c.9198G>A p.P3066= | Silent (SNP) | VAF 67/102 reads (66%) | catalogued as rs147557959; called by muse, mutect2, varscan2
- RNFT2 | c.795C>T p.I265= | Silent (SNP) | VAF 64/213 reads (30%) | catalogued as rs779374430, COSV57485216; called by muse, mutect2, varscan2
- RPS6KL1 | c.993G>A p.R331= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV63581124; called by muse, mutect2, varscan2
- RPTOR | c.3075C>T p.V1025= | Silent (SNP) | VAF 32/83 reads (39%) | catalogued as rs900155152, COSV60812004; called by muse, mutect2, varscan2
- SAFB | c.1323C>T p.A441= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV52651271; called by muse, mutect2, varscan2
- SAFB2 | c.2628C>T p.A876= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV53042374; called by muse, mutect2, varscan2
- SAMD9L | c.4515C>T p.S1505= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV59081405; called by muse, mutect2, varscan2
- SBK1 | c.753C>T p.F251= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV59396947; called by muse, mutect2, varscan2
- SCN3A | c.2409C>T p.F803= | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as rs267598955, COSV51809232; called by muse, mutect2, varscan2
- SEMA5B | c.1065C>T p.Y355= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV52097263; called by muse, mutect2, varscan2
- SERPINB6 | c.1092C>T p.F364= (on ENST00000612421 / NM_001271823.2; = p.F345= on NM_004568.6) | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs775311683, COSV59565324; called by muse, mutect2, varscan2
- SHOX2 | c.477T>C p.F159= (on ENST00000441443 / NM_006884.3; = p.F183= on NM_003030.4) | Silent (SNP) | VAF 10/129 reads (8%) | catalogued as rs1559896995, COSV67463871; called by muse, mutect2
- SIPA1L3 | c.207C>T p.P69= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV55913751; called by muse, mutect2, varscan2
- SLAMF6 | c.24C>T p.L8= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV63587051; called by muse, mutect2, varscan2
- SLC30A4 | c.621C>T p.I207= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV56005921; called by muse, mutect2, varscan2
- SLC5A5 | c.486G>A p.L162= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV55832902; called by muse, mutect2, varscan2
- SLC5A7 | c.939A>G p.T313= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs778842636, COSV50891307; called by mutect2, varscan2
- SMPD4 | c.702C>T p.F234= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV60080104; called by muse, mutect2, varscan2
- SNCG | c.102G>A p.K34= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV62318152; called by muse, mutect2, varscan2
- SPAG16 | c.1470C>T p.S490= | Silent (SNP) | VAF 17/130 reads (13%) | catalogued as COSV59091640; called by muse, mutect2, varscan2
- SSTR3 | c.141C>T p.I47= | Silent (SNP) | VAF 17/143 reads (12%) | catalogued as rs1167913607, COSV60729310; called by muse, mutect2, varscan2
- STRN4 | c.426C>T p.N142= | Silent (SNP) | VAF 36/141 reads (26%) | catalogued as COSV99624001; called by muse, mutect2, varscan2
- SURF6 | c.375C>T p.I125= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV63292773; called by muse, mutect2
- SV2C | c.1878C>T p.F626= | Silent (SNP) | VAF 31/141 reads (22%) | catalogued as COSV100456757; called by muse, mutect2, varscan2
- SYK | c.1819C>T p.L607= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV65327020; called by muse, mutect2
- TAOK1 | c.1662C>T p.S554= | Silent (SNP) | VAF 58/109 reads (53%) | catalogued as rs767709666, COSV55591435; called by muse, mutect2, varscan2
- TBC1D19 | c.1580G>A p.*527= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV53516653; called by muse, mutect2, varscan2
- TENM1 | c.1557A>C p.V519= | Silent (SNP) | VAF 40/82 reads (49%) | catalogued as COSV64431319; called by muse, mutect2, varscan2
- TH | c.351C>T p.F117= (on ENST00000381178 / NM_199292.3; = p.F86= on NM_000360.4) | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV60767308; called by muse, mutect2
- THSD4 | c.1902G>A p.G634= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV55969580; called by muse, mutect2, varscan2
- TLN2 | c.1359G>A p.P453= | Silent (SNP) | VAF 43/125 reads (34%) | catalogued as rs767329386, COSV60889526; called by muse, mutect2, varscan2
- TMPRSS7 | c.1587C>T p.S529= (on ENST00000452346; = p.S403= on NM_001042575.2) | Silent (SNP) | VAF 41/147 reads (28%) | catalogued as COSV69980589; called by muse, mutect2, varscan2
- TNR | c.3519C>T p.D1173= | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as rs373290989; called by muse, mutect2, varscan2
- TPO | c.1395G>A p.Q465= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV61101390; called by muse, mutect2, varscan2
- TRIM56 | c.606C>T p.C202= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV60158832; called by muse, mutect2
- TRPM2 | c.570C>T p.F190= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV55969437; called by muse, mutect2, varscan2
- TSHZ1 | c.1182C>T p.N394= (on ENST00000580243 / NM_001308210.2; = p.N349= on NM_005786.6) | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV59009064; called by muse, mutect2, varscan2
- TSNARE1 | c.1335C>T p.S445= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as COSV56175435; called by muse, mutect2, varscan2
- TTN | c.40986G>A p.R13662= (on ENST00000591111; = p.R6238= on NM_003319.4) | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs759025428, COSV60042673; called by muse, mutect2, varscan2
- TTN | c.5820G>A p.R1940= (on ENST00000591111; = p.R1894= on NM_003319.4) | Silent (SNP) | VAF 39/203 reads (19%) | catalogued as COSV60042705; called by muse, mutect2, varscan2
- UBE3D | c.504C>T p.F168= | Silent (SNP) | VAF 16/112 reads (14%) | catalogued as COSV52753532; called by muse, varscan2
- UROC1 | c.1839G>A p.P613= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs1025426485, COSV52032867; called by muse, mutect2, varscan2
- USP9X | c.3472T>C p.L1158= | Silent (SNP) | VAF 18/24 reads (75%) | catalogued as COSV61068961; called by muse, mutect2, varscan2
- VASN | c.972G>A p.E324= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV52029856; called by muse, mutect2, varscan2
- ZCCHC4 | c.270C>T p.A90= | Silent (SNP) | VAF 47/153 reads (31%) | catalogued as rs1171091106, COSV57181260; called by muse, mutect2, varscan2
- ZFP82 | c.1299A>C p.L433= | Silent (SNP) | VAF 20/101 reads (20%) | catalogued as COSV67565279; called by muse, mutect2, varscan2
- ZFP90 | c.1683C>T p.A561= | Silent (SNP) | VAF 57/147 reads (39%) | catalogued as COSV68050929; called by muse, mutect2, varscan2
- ZNF408 | c.1353C>A p.S451= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as COSV61238113; called by muse, mutect2, varscan2
- AP001425.1 | chr21:38208185 G>A | 5'Flank (SNP) | VAF 12/62 reads (19%) | catalogued as rs771936716; called by muse, mutect2, varscan2
- CSF2RA | c.*48C>T | 3'UTR (SNP) | VAF 55/181 reads (30%) | catalogued as rs368547679, COSV100817767; called by muse, mutect2, varscan2
- CTBP2 | c.58+12529C>T | Intron (SNP) | VAF 7/24 reads (29%) | catalogued as rs761255551, COSV100456869; called by muse, mutect2, varscan2
- MGAM | c.4618+301C>T | Intron (SNP) | VAF 45/120 reads (38%) | catalogued as rs1199033944, COSV72075117; called by muse, mutect2, varscan2
- MGAM | c.4618+8663G>A | Intron (SNP) | VAF 11/85 reads (13%) | catalogued as COSV72073784; called by muse, mutect2, varscan2
- PKD1L2 | n.3213G>T | RNA (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2
- SNORD115-12 | n.16A>G | RNA (SNP) | VAF 132/454 reads (29%) | called by muse, mutect2, varscan2
- TPM1 | c.563+266C>T | Intron (SNP) | VAF 30/70 reads (43%) | catalogued as rs201813515, COSV51265513; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.10361-3963G>A | Intron (SNP) | VAF 27/145 reads (19%) | catalogued as COSV100627475; called by muse, mutect2, varscan2
- USH1C | c.1284+1128C>T | Intron (SNP) | VAF 4/20 reads (20%) | catalogued as rs780885203, COSV50032972, COSV99139617; called by muse, mutect2
- UVSSA | c.*9781C>T | 3'UTR (SNP) | VAF 57/153 reads (37%) | catalogued as rs746378277, COSV61348875; called by muse, mutect2, varscan2
